Gene-level copy-number profile of tumor specimen BLGSP-71-06-00012-01B from CGCI case BLGSP-71-06-00012, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00012-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a5d7816b-3e7b-403c-982c-93953b78d602.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00012-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/5e1cf449-c3b8-4c76-8fba-fdda84aa24af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 3,100; copy number 2: 54,427; copy number 3: 1,247; copy number 4: 39; copy number 5: 4; copy number 6: 1; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,915,081–88,979,081, 6 genes (within-gene range 0–2): IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7.
- chr4:9,234,385–9,269,211, 8 genes (within-gene range 0–2): USP17L15, USP17L16P, USP17L17, USP17L18, USP17L19, USP17L20, USP17L21, USP17L22.
- chr14:105,851,705–106,122,709, 62 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,415,352–70,448,015, 1 gene, copy number 16: GTF2H2B.
- chr5:70,516,387–70,795,914, 3 genes, copy number 5: GUSBP15, GUSBP16, AC139272.1.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr21:13,038,160–13,067,033, 1 gene, copy number 5 (within-gene range 3–5): ANKRD30BP2.

Autosomal genes at a single copy (total copy number 1): 244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
